Somatic mutation profile of tumor specimen 0DH733 from CCDI case PBBRUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sertoli-Leydig cell tumor, poorly differentiated; Tissue or organ of origin: Ovary; Age at diagnosis: 14.1 years (5,155 days).
Specimen 0DH733: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 704168d5-8f9d-4424-a647-b15366d83974.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH6ZZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33a59dcc-f6bd-4f0d-9a24-073c5abfabb6

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 192/481 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, varscan2
- ERVW-1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as rs777447724, COSV71259377; called by muse, varscan2
- F12 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 261/636 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775251344; called by muse, varscan2
- FAM234B | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 500/858 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs747104306, COSV52196792, COSV99545582; called by muse, varscan2
- HES4 | c.371T>A p.F124Y | Missense Mutation (SNP) | VAF 134/316 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); called by muse, varscan2
- RAB3GAP2 | c.1281C>T p.D427= | Silent (SNP) | VAF 198/478 reads (41%) | catalogued as rs372594666; ClinVar: likely benign; called by muse, varscan2
- HNF4A-AS1 | n.356+1364C>T | Intron (SNP) | VAF 158/372 reads (42%) | catalogued as rs921046811; called by muse, varscan2
- TRAPPC3L | c.-35A>G | 5'UTR (SNP) | VAF 86/218 reads (39%) | called by muse, varscan2
